Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4TJ, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4TJ-01A (Primary Tumor).

10/29/12

Surgical Pathology

REVISED REPORT (Addendum/Procedure included)
Requested By:

TISSUE DESCRIPTION:

A1 A2 B1 B2 C1 D1 D2 D3 D4 D5 D6 D7 D8 E1 F1 F2 F3 F4 F5
Tissue from the right upper lobe lung (7.2 x 6.5 x 3.5 cm), right upper lobe lung (95.0 grams), station 4R (2 sets), 7 and 12 lymph nodes.

DIAGNOSIS:

Lung, right upper lobe, wedge excision: Invasive grade 3 (of 4) adenocarcinoma with signet ring cell features, forming a 2.5 x 2.4 x 2.4 cm mass. The tumor focally involves the stapled margin. The pleura is uninvolved. A calcified granuloma is also present.

Lung, right upper lobe, completion lobectomy: No residual tumor identified. The bronchial margin is negative for malignancy.

Lymph nodes, mediastinal, excision:

- No tumor is identified in multiple (6) right lower paratracheal (station 4R) lymph nodes. One of the lymph nodes shows necrotizing granulomatous inflammation.

- No tumor is identified in a single (1) subcarinal (station 7) lymph node. Necrotizing granulomatous inflammation is identified. Special stains (AR and GMS) will be performed and reported in an addendum.

Lymph nodes, intrapulmonary/hilar lymph nodes excision:

- Multiple (3) intrapulmonary peribronchial lymph nodes are negative for malignancy. One of the lymph nodes show necrotizing granulomatous inflammation.

- No tumor is identified in a single (1) lobar (station 12) lymph node.

ADDENDUM:

Special stains (x2) for organisms (AR and GMS) performed on the lymph nodes are negative.

1CD-0-3

adenocarcinoma, signet ring cell 8490/3
Site: lung, ^(R) upper lobe c34.1

10/29/12

Source: NCI Genomic Data Commons file b3b1e269-1735-4107-8e6e-6ba9e9318c68 (TCGA-MP-A4TJ.23EC6DA5-7109-4E11-B2BC-F1EDC7DF0ED3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).